Gene-level copy-number profile of tumor specimen TCGA-VN-A88O-01A from TCGA case TCGA-VN-A88O, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.1 years (17,945 days).
Specimen TCGA-VN-A88O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.433e578d-ff8e-46bd-976d-203a1dbbd180.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VN-A88O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b18409bc-976a-4991-b4ba-80c557a245df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,414; copy number 1: 4,853; copy number 2: 52,757; copy number 3: 182; copy number 4: 4; copy number 5: 14; copy number 8: 9; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VN-A88O-01A-11D-A34T-01): tumor purity 0.33, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr1:102,199,739–103,108,872, 4 genes: AC114485.1, AC099567.1, COL11A1, SOD2P1.
- chr1:175,538,775–175,556,818, 1 gene: TNR-IT1.
- chr8:39,451,045–39,730,065, 3 genes (within-gene range 0–1): ADAM3A, AC123767.1, ADAM18.
- chr9:60,914,407–61,627,683, 15 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:388,412–749,856, 14 genes, copy number 5 (within-gene range 2–5): AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1.
- chr10:95,109,136–95,111,642, 1 gene, copy number 14: AL157834.1.
- chr15:61,852,389–62,060,473, 1 gene, copy number 8 (within-gene range 2–8): VPS13C.
- chr15:62,060,503–62,253,235, 8 genes, copy number 8: AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 4,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
